Somatic mutation profile of tumor specimen MP2PRT-PAVWUM-TMP1-A (aliquot MP2PRT-PAVWUM-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVWUM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,032 days).
Specimen MP2PRT-PAVWUM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f97aa18e-6b79-493b-a8c4-fbc02c5fc154.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVWUM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVWUM-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53e8ed17-fb47-4fbb-b50d-8cbee9ddc5e5

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Ins 1, 3'Flank 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 47/270 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 59/425 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs769453411, COSV63971747; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BUB1B | c.2538T>A p.D846E | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.338); catalogued as rs372003254; called by muse, mutect2, varscan2
- COL11A1 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.932); catalogued as COSV62183345; called by muse, mutect2
- GHSR | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 112/561 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53840672; called by muse, mutect2
- HNF4G | c.748G>T p.A250S (on ENST00000354370 / NM_001330561.2; = p.A297S on NM_004133.5) | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as rs763679635; called by muse, mutect2, varscan2
- HS6ST3 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 64/405 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs778619413, COSV65009566; called by muse, mutect2, varscan2
- MS4A4A | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 22/176 reads (13%) | catalogued as COSV59701223; called by muse, mutect2, varscan2
- SPEG | c.3337C>T p.R1113W | Missense Mutation (SNP) | VAF 61/357 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1037617565; called by muse, mutect2, varscan2
- STS | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 24/627 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.711); catalogued as COSV54268770, COSV54272840; called by muse, mutect2
- ZPBP | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 106/276 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs371753916, COSV50422674; called by muse, mutect2, varscan2
- DMXL1 | c.1642A>C p.M548L | Missense Mutation (SNP) | VAF 58/371 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGKV1D-8 | c.262_263dup p.S89Dfs*? | Frame Shift Ins (INS) | VAF 34/260 reads (13%) | called by mutect2, pindel, varscan2
- OR10C1 | c.889G>A p.E297K (on ENST00000622521; = p.E295K on NM_013941.3) | Missense Mutation (SNP) | VAF 89/637 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- OR2M3 | c.71A>G p.H24R | Missense Mutation (SNP) | VAF 70/474 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- ATG2B | c.6225C>T p.H2075= | Silent (SNP) | VAF 30/222 reads (14%) | catalogued as rs754870777, COSV55889906; called by muse, mutect2, varscan2
- OTOG | c.1347C>T p.I449= | Silent (SNP) | VAF 61/340 reads (18%) | catalogued as rs1457839484; called by muse, mutect2, varscan2
- PPP1R3G | c.418C>T p.L140= | Silent (SNP) | VAF 22/768 reads (3%) | called by muse, mutect2
- CMTM3 | c.520+848C>T | Intron (SNP) | VAF 139/415 reads (33%) | called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928467 G>A | 3'Flank (SNP) | VAF 77/515 reads (15%) | called by muse, mutect2, varscan2
